Somatic mutation profile of tumor specimen 0DD53K from CCDI case PBBLWR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain stem; Age at diagnosis: 9.4 years (3,444 days).
Specimen 0DD53K: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a18d4bc-a838-42c7-a6c2-cdf83f9d30b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DD53G (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/335989ce-1d55-48bc-8584-0ce3b7734158

The open-access MAF lists 24 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, 3'UTR 4, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 154/617 reads (25%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 139/278 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519989, CM144215, COSV52668392, COSV52676997, COSV52808251; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GABRG1 | c.1195G>T p.E399* | Nonsense Mutation (SNP) | VAF 523/1537 reads (34%) | catalogued as COSV104402036; called by muse, mutect2, varscan2
- KCTD19 | c.695T>C p.I232T | Missense Mutation (SNP) | VAF 72/569 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.366); catalogued as rs146555775; called by muse, mutect2, varscan2
- TMEM94 | c.652C>A p.P218T | Missense Mutation (SNP) | VAF 88/317 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.888); catalogued as COSV58593520; called by mutect2, varscan2
- ZNF598 | c.2509C>T p.R837C | Missense Mutation (SNP) | VAF 107/289 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as rs778468856; called by muse, mutect2, varscan2
- ANGPT1 | c.53G>C p.G18A | Missense Mutation (SNP) | VAF 288/813 reads (35%) | SIFT tolerated (0.81); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- CASP4 | c.641A>G p.E214G | Missense Mutation (SNP) | VAF 359/894 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FRY | c.4480C>G p.L1494V | Missense Mutation (SNP) | VAF 15/380 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- OR4C46 | c.27G>T p.E9D | Missense Mutation (SNP) | VAF 107/272 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- PSMC4 | c.1211A>G p.K404R | Missense Mutation (SNP) | VAF 17/601 reads (3%) | SIFT tolerated (0.37); PolyPhen benign (0.047); called by muse, mutect2
- RYR2 | c.9472T>G p.C3158G | Missense Mutation (SNP) | VAF 156/1073 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- SLC15A1 | c.488T>C p.F163S | Missense Mutation (SNP) | VAF 35/542 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- TRIM32 | c.671A>C p.Q224P | Missense Mutation (SNP) | VAF 17/492 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2
- TSHZ3 | c.3148T>G p.F1050V | Missense Mutation (SNP) | VAF 23/548 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZBED9 | c.1291C>A p.P431T | Missense Mutation (SNP) | VAF 157/516 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DUOXA2 | c.258C>G p.S86= | Silent (SNP) | VAF 14/288 reads (5%) | called by muse, mutect2
- EVPL | c.663C>T p.R221= | Silent (SNP) | VAF 254/463 reads (55%) | catalogued as rs763191500, COSV56912837; called by muse, mutect2, varscan2
- NPTX2 | c.1236G>C p.V412= | Silent (SNP) | VAF 89/318 reads (28%) | catalogued as COSV55716603; called by muse, mutect2, varscan2
- OR5W2 | c.732C>T p.H244= | Silent (SNP) | VAF 249/718 reads (35%) | called by muse, mutect2, varscan2
- FCSK | c.*37C>T | 3'UTR (SNP) | VAF 31/80 reads (39%) | called by muse, mutect2, varscan2
- RAPSN | c.*26T>G | 3'UTR (SNP) | VAF 55/162 reads (34%) | called by muse, mutect2, varscan2
- ZNF292 | c.*32A>G | 3'UTR (SNP) | VAF 76/184 reads (41%) | called by muse, mutect2, varscan2
- ZNF567 | c.*97C>T | 3'UTR (SNP) | VAF 13/141 reads (9%) | catalogued as rs999955723; called by muse, mutect2
